Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A75P, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A75P-01A (Primary Tumor).

Final Diagnosis:

A-B. Brain, hippocampus mass and left temporal lobe, biopsies: Low-grade diffuse astrocytoma (WHO grade II).
(See comment).

Immunoperoxidase studies were performed on paraffin sections (block A2) using antibodies directed against the following antigens: GFAP, IDH1-R132H, p53, EMA, neurofilament protein, and Ki-67.

GFAP: Positive.

Neurofilament protein: Highlights axons within the tumor.

Ki-67: Low proliferative index.

IDH1-R132H: Negative.

p53: Low to moderate labeling.

EMA: Negative.

Comment: The lesion has a relatively high level of cellularity in areas; however, the Ki-67 labeling index is low and mitotic activity is not apparent.

Seen in consultation with

Interpreted by:

Report electronically signed by

Transcribed by:

continued next page Page 1 of 3

ICD-O-3
Astrocytoma, grade II
9400/3
Site ④ Brain, supratentorial
C71.0
JW 8/12/13

Source: NCI Genomic Data Commons file 6c207cc0-1894-4850-ba88-fe978edefd6b (TCGA-DB-A75P.6CD48114-C318-4450-AADD-62E3CE7ED427.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).